Surgical pathology report (de-identified scan), TCGA case TCGA-06-6390, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-6390-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

CLINICAL HISTORY

Brain tumor

OPERATIVE DIAGNOSES

Operation/Specimen: A: Right frontal tumor, resection
B: Corpus collosum, resection

PATHOLOGICAL DIAGNOSIS:

A. Right frontal tumor, resection: High-grade mixed glioma (see comment).

B. Corpus collosum, resection: Cerebral cortex, no evidence of tumor.

COMMENT

Sections show a classic appearing oligodendroglial neoplasm centered in the deep white matter. Mitotic figures are readily identified. The deeper, possibly intraventricular portions of the tumor show a papillary structure with astroblastoma type cells forming perivascular rosettes, best seen by GFAP immunostain. There are also areas of astrogliosis, vascular proliferation and hyalinized necrosis however these show features suggesting that they are reactive to prior treatment, e.g., radiation.

The tumor is diffusely weak to moderately p53 positive and the Ki-67 labeling index is focally up to approximately 30%.

Given the presence of the astroblastoma-like component, and that the previous resection from this patient was interpreted as an astrocytoma, the tumor may perhaps best be considered a high-grade mixed glioma. Considering the findings

of this and the previous resection specimen, ~~glioblastoma~~ would be a diagnostic consideration, although not all histologic features are definitely

~~present in either specimen.~~ The major infiltrative component of this lesion

[page 2 of 4]
however is anaplastic oligodendroglioma. Clinical correlation is required.

PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are:

D1S548, D1S1592, D1S552, D19S219, D19S412, and PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

DNA extracted from a corresponding blood specimen was used as normal reference control.

A slide was examined and tumor DNA was enriched by microdissection.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers

on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as

backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C

(with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the

first line markers at that chromosome arm are uninformative or otherwise

ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p

and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a

stand-alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

[page 3 of 4]
the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample

may preclude the detection of allelic loss.

Electronically Signed Out

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing was performed on microdissected tissue from case

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or

extensive tissue necrosis, may preclude the detection of methylated MGMT

promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

=====

GROSS DESCRIPTION

A. Right frontal tumor, resection:

CONTAINER LABEL: right frontal tumor

FIXATIVE: Formalin. NO. PIECES: 1. SIZE/VOL: 3 x 2.5 x 1.5 cm
portion of

[page 4 of 4]
gray-white soft hemorrhagic tissue. CASSETTES: 3, [REDACTED].

B. Corpus collosum, resection:

CONTAINER LABEL: corpus callosum.

FIXATIVE: Formalin. NO. PIECES: 1. SIZE/VOL: 5 x 3 x 2 mm soft pink-tan

hemorrhagic tissue fragment. CASSETTES: 1, [REDACTED]

ICD-9(s):

191.0 191.0

Histo Data

Part A: Right frontal tumor, resection

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
EMA-DA x 1	2	[REDACTED]	
mGFAP-DA x 1	2	[REDACTED]	
H/E x 1	2	[REDACTED]	
LOH-slides x 1	2	[REDACTED]	
MGMT-slides x 1	2	[REDACTED]	
Rct 1 H/E x 1	2	[REDACTED]	
mGFAP-DA x 1	3	[REDACTED]	
H/E x 1	3	[REDACTED]	
MIB1-DA x 1	3	[REDACTED]	
P53DO7 x 1	3	[REDACTED]	
Rct 1 H/E x 1	3	[REDACTED]	

Part B: Corpus collosum, resection

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 67e95752-e2bd-4818-a134-d216f258f95c (TCGA-06-6390.DFCAD656-40F1-4ECF-A516-BC1FD73D66C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).